Somatic mutation profile of cancer-model specimen HCM-CSHL-0817-C22-85A (3D Organoid, passage 10; aliquot HCM-CSHL-0817-C22-85A-01D-A85L-36), derived from the primary tumor of HCMI case HCM-CSHL-0817-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 75.3 years (27,513 days).
Specimen HCM-CSHL-0817-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09d4ac22-88e0-4a00-bdff-8db8c3297408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0817-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0817-C22-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/225b6245-f76e-4e9f-8528-2973e9cf9fe7

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Nonsense Mutation 3, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA9 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs765834807, COSV100253321; called by muse, mutect2, varscan2
- EPHA2 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 329/329 reads (100%) | catalogued as COSV64452291; called by muse, mutect2, varscan2
- ETNPPL | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 55/227 reads (24%) | catalogued as rs146606272; called by muse, mutect2, varscan2
- FAT3 | c.12637C>T p.R4213C | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as rs1389737720, COSV53144188; called by muse, mutect2, varscan2
- HIBCH | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 167/353 reads (47%) | catalogued as rs1357291112; called by muse, mutect2, varscan2
- KCNK4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs1486888231; called by muse, mutect2, varscan2
- OLFML2A | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484505521; called by muse, mutect2, varscan2
- OR2C3 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV63576147; called by muse, mutect2, varscan2
- PPP2R1B | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 169/365 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs555421329; called by muse, mutect2, varscan2
- SPTB | c.6103G>A p.G2035R | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1206516197; called by muse, mutect2, varscan2
- SUSD4 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 246/472 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs906392405; called by muse, mutect2, varscan2
- TCF7L2 | c.85_87del p.E29del | In Frame Del (DEL) | VAF 204/456 reads (45%) | catalogued as rs754968616; called by pindel, varscan2
- BCORL1 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 169/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- DMXL2 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 165/356 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM166B | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- HAMP | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 124/473 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HERC6 | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- IGSF8 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 173/632 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NPR1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 192/448 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITPNM1 | c.1586A>G p.Q529R | Missense Mutation (SNP) | VAF 311/626 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PRAMEF19 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 136/565 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.046); called by muse, mutect2
- SETD1B | c.5338G>A p.G1780S | Missense Mutation (SNP) | VAF 199/384 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TRPC5OS | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TYR | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 175/348 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC13C | c.4705A>G p.T1569A | Missense Mutation (SNP) | VAF 124/230 reads (54%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF654 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 80/541 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASXL3 | c.1221C>T p.S407= | Silent (SNP) | VAF 112/326 reads (34%) | called by muse, varscan2
- C1QB | c.132A>C p.T44= | Silent (SNP) | VAF 214/214 reads (100%) | called by muse, mutect2, varscan2
- CELA3A | c.456C>G p.P152= | Silent (SNP) | VAF 291/296 reads (98%) | called by muse, mutect2, varscan2
- DGKD | c.2826C>T p.D942= (on ENST00000264057 / NM_152879.3; = p.D898= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/331 reads (24%) | called by muse, mutect2, varscan2
- FAM47A | c.829C>A p.R277= | Silent (SNP) | VAF 292/450 reads (65%) | catalogued as COSV60499024; called by muse, mutect2, varscan2
- RHBDF1 | c.1980C>T p.L660= | Silent (SNP) | VAF 162/367 reads (44%) | catalogued as rs1019559193; called by muse, mutect2, varscan2
- SDC3 | c.69C>T p.A23= | Silent (SNP) | VAF 42/151 reads (28%) | called by muse, varscan2
- SEPTIN4 | c.1380C>T p.S460= | Silent (SNP) | VAF 203/437 reads (46%) | catalogued as rs149667618; called by muse, mutect2, varscan2
- TTN | c.8604C>T p.V2868= (on ENST00000591111; = p.V2822= on NM_003319.4) | Silent (SNP) | VAF 188/412 reads (46%) | catalogued as rs753733308, COSV60176747; called by muse, mutect2, varscan2
- ZNF729 | c.1074C>T p.S358= | Silent (SNP) | VAF 86/430 reads (20%) | catalogued as rs773424107; called by muse, mutect2, varscan2
- AL132655.7 | n.53C>T | RNA (SNP) | VAF 281/548 reads (51%) | catalogued as COSV100008251; called by muse, mutect2, varscan2
- IPO13 | c.-402A>G | 5'UTR (SNP) | VAF 146/615 reads (24%) | catalogued as rs1202908988; called by muse, mutect2, varscan2
